FM case AD3627 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/590c9d6b-0d66-4dd3-a4d8-1428dbb1db61

Female, 59.3 years: Metaplastic carcinoma, NOS (ICD-O-3 8575/3) of the breast; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
